Somatic mutation profile of tumor specimen MP2PRT-PAPBZN-TMP1-A (aliquot MP2PRT-PAPBZN-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PAPBZN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.2 years (451 days).
Specimen MP2PRT-PAPBZN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8db2da9-613b-4dc5-a754-3b5922a9a9c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPBZN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPBZN-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b792a2b2-e4fc-44c7-96da-510b3c885865

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMACR | c.731T>C p.L244P | Missense Mutation (SNP) | VAF 107/309 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100163144; called by muse, mutect2, varscan2
- NPAS3 | c.782G>A p.R261H (on ENST00000356141 / NM_001164749.2; = p.R229H on NM_022123.3) | Missense Mutation (SNP) | VAF 176/400 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs950848692, COSV60835482, COSV60855705; called by muse, mutect2, varscan2
- PHYHIPL | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 35/101 reads (35%) | catalogued as COSV65848507; called by muse, mutect2, varscan2
- SRGAP1 | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 155/550 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.772); catalogued as rs765568604; called by muse, mutect2, varscan2
- TENM2 | c.5125C>T p.R1709C (on ENST00000518659 / NM_001122679.2; = p.R1470C on NM_001080428.3) | Missense Mutation (SNP) | VAF 128/327 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs545423425; called by muse, mutect2, varscan2
- ANKRD28 | c.3145G>A p.D1049N | Missense Mutation (SNP) | VAF 117/282 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- COL21A1 | c.473C>A p.A158E | Missense Mutation (SNP) | VAF 176/427 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUTM2E | c.363G>T p.E121D | Missense Mutation (SNP) | VAF 148/446 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.262); called by muse, mutect2
- SOX6 | c.714G>A p.A238= | Silent (SNP) | VAF 102/225 reads (45%) | catalogued as rs1364098469; called by muse, mutect2, varscan2
